Gene-level copy-number profile of tumor specimen ALCH-B1OB-TTR1-A from ALCHEMIST case ALCH-B1OB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.0 years (25,941 days).
Specimen ALCH-B1OB-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0b56d754-1408-46ad-a1ca-a80c62eea239.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1OB-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,729 have no estimate.
https://portal.gdc.cancer.gov/files/73b2df8a-d76c-442e-a4da-06271964997b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 42; copy number 1: 76; copy number 2: 16,355; copy number 3: 419; copy number 4: 31,340; copy number 5: 860; copy number 6: 5,533; copy number 7: 304; copy number 8: 2,923; copy number 9: 358; copy number 10: 224; copy number 11: 211; copy number 12: 114; copy number 13: 51; copy number 14: 17; copy number 15: 14; copy number 17: 6; copy number 20: 1; copy number 21: 35; copy number 25: 11.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:52,473–71,585, 3 genes: OR4G4P, OR4G11P, OR4F5.
- chr1:89,551–91,105, 1 gene (within-gene range 0–4): AL627309.3.
- chr4:154,523,487–154,524,807, 1 gene: AC110753.1.
- chr6:29,896,654–29,908,645, 3 genes: HLA-T, DDX39BP1, MCCD1P1.
- chr8:8,086,022–8,116,949, 4 genes: AC105233.2, MIR548I3, RPS3AP31, SNRPCP17.
- chr13:30,880,912–32,778,019, 29 genes (within-gene range 0–2): LINC00545, TEX26-AS1, MEDAG, TEX26, AL353680.1, LINC01066, WDR95P, HSPH1, B3GLCT, ANKRD26P4, AL161616.2, AL161616.1, RXFP2, FRY, EEF1DP3, AC002525.1, Metazoa_SRP, FRY-AS1, ZAR1L, BRCA2, IFIT1P1, N4BP2L1, AL137247.1, AL137247.2, N4BP2L2, ATP8A2P2, N4BP2L2-IT2, PDS5B, RNY1P4.
- chr16:2,830,169–2,839,585, 1 gene (within-gene range 0–2): ZG16B.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,042 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,789,030–153,923,360, 1 gene, copy number 11 (within-gene range 8–11): GATAD2B.
- chr1:153,890,595–156,800,815, 171 genes, copy number 11 (broad region; genes not listed).
- chr1:223,538,007–223,665,723, 2 genes, copy number 12: CAPN8, SNRPEP10.
- chr3:164,978,898–166,181,820, 11 genes, copy number 9: SI, Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2.
- chr3:168,249,522–168,830,599, 1 gene, copy number 9 (within-gene range 8–9): EGFEM1P.
- chr3:168,551,854–169,038,416, 7 genes, copy number 9: MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr3:178,272,932–183,812,624, 106 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr3:183,815,922–183,825,594, 1 gene, copy number 10: MAP6D1.
- chr5:58,198–8,717,883, 171 genes, copy number 9–13 (broad region; genes not listed).
- chr5:15,384,220–43,707,405, 400 genes, copy number 9–15 (broad region; genes not listed).
- chr5:52,673,186–58,558,243, 113 genes, copy number 10–25 (broad region; genes not listed).
- chr6:37,005,646–38,640,148, 26 genes, copy number 9–11 (within-gene range 4–11): FGD2, COX6A1P2, RPL12P2, PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P, CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3, MDGA1, AL121574.1, ZFAND3, RN7SL285P, RNVU1-33, AL589655.1, BTBD9, AL033518.1.
- chr12:53,210,567–53,232,980, 1 gene, copy number 9: RARG.
- chr22:22,686,726–22,693,312, 3 genes, copy number 9: IGLV3-25, AC244250.2, AC244250.1.
- chr22:23,145,326–23,717,356, 28 genes, copy number 9: RAB36, BCR, BCRP8, RN7SL263P, FBXW4P1, AP000343.1, LINC02556, CES5AP1, ZDHHC8P1, AP000344.2, LINC01659, AP000344.1, FAM230I, AP000345.3, LINC02557, PCAT14, AP000345.1, IGLL1, AP000345.2, AP000346.4, DRICH1, AP000346.3, AP000346.1, GUSBP11, AP000346.2, ASLP1, AP000347.1, RGL4.

Autosomal genes at a single copy (total copy number 1): 18. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
